Surgical pathology report (de-identified scan), TCGA case TCGA-J4-AATZ, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J4-AATZ-01A (Primary Tumor).

[page 1 of 5]
Gender

M

Date Of Birth

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected

Time Received

Time Reported

Order Number

Ordering Provider

Status

Final

Results

Final

Source of Specimen

- A. LEFT PELVIC NODE FS-
- B. LEFT PELVIC NODE NFS-
- C. RIGHT PELVIC NODE FS-
- D. RIGHT PELVIC NODE NFS-
- E. BLADDER NECK FS-
- F. PROSTATE, VAS & SEMINAL VESICLES-NFS-

ICD O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
JS 5/28/14

FINAL DIAGNOSIS:

- A. LEFT PELVIC NODE FS-
TWO LYMPH NODES, NO TUMOR SEEN.
- B. LEFT PELVIC NODE NFS-
MULTIPLE LYMPH NODE FRAGMENTS, NO TUMOR SEEN.
- C. RIGHT PELVIC NODE FS-
TWO LYMPH NODES, NO TUMOR SEEN.
- D. RIGHT PELVIC NODE NFS-
MULTIPLE LYMPH NODE FRAGMENTS, NO TUMOR SEEN.
- E. BLADDER NECK FS-
NO TUMOR SEEN.
- F. PROSTATE, VAS & SEMINAL VESICLES-NFS-
ADENOCARCINOMA OF PROSTATE WITH UNILATERAL EXTENSION INTO
EXTRAPROSTATIC SOFT TISSUE.

TUMOR SITE: RIGHT APEX, RIGHT AND LEFT PERIPHERAL ZONES,
PREDOMINANTLY RIGHT-SIDED.

SPECIMEN TYPE: RADICAL PROSTATECTOMY.

WEIGHT: 50 GRAMS. SIZE: 4.5 x 4 x 3 CM.

Prepared for

[page 2 of 5]
GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 4 + 5 = 9/10.

TERTIARY PATTERN: NOT PRESENT.

SEVERITY IN EXTENT OF TUMOR: 4 /5.

(1: <5%; 2: 5-15%; 3: 15-30%; 4: 30-50%; 5: > 50% tissue involvement).

DOMINANT NODULE (AT LEAST 1 CM IN SIZE): NOT PRESENT.

TREATMENT EFFECT ON CARCINOMA: NOT IDENTIFIED.

LYMPH NODE(S) INCLUDED IN ALL PARTS: NUMBER INVOLVED : 0
NUMBER EXAMINED: 4

TNM STAGE: pT3a, pN0, pMX.

(Extraprostatic extension or microscopic invasion of bladder neck)

(N0: negative node; N1: positive regional node)

LYMPHATIC (SMALL VESSEL) INVASION: NOT SEEN.

PERINEURAL INVASION: IS PRESENT.

NO TUMOR SEEN IN SEMINAL VESICLES.

NO TUMOR SEEN AT MARGINS OF URETHRA AND BLADDER NECK.

TUMOR IS SEEN AT INKED APICAL MARGIN, RIGHT SIDE.

Signature

(Case signed

Signed Others

Frozen Section

A. LEFT PELVIC LYMPH NODES: 2 LYMPH NODES; REPRESENTATIVE
SECTIONS: NTS (0/2).

RIGHT PELVIC LYMPH NODES: 2 LYMPH NODES; REPRESENTATIVE
SECTIONS: NTS (0/2).

BLADDER NECK: NTS.

FS performed by

Prepared for

[page 3 of 5]
(Frozen Section Signed

Case Clinical Information
PROSTATE CA

Gross Description

A. Received in formalin labeled with the patient's name and "left pelvic node FS" consists of two gray-tan FS tissue fragments. The larger measures 2.2 x 0.7 cm and the smaller measures 1 x 0.7 cm. Submitted complete in A1.

B. Received in formalin labeled with the patient's name and "left pelvic node NFS" is an aggregate of yellow, fibrofatty tissue fragments measuring 3.5 x 3 cm. The fat is trimmed and two probable lymph nodes are grossly identified. The larger measures 1 x 0.5 cm. The smaller measures 0.5 x 0.5 cm. The remainder of the specimen is submitted complete in B2-B5.

C. Received in formalin labeled with the patient's name and "right pelvic nodes FS" are two gray-tan FS tissue fragments. The larger measures 2 x 0.7 cm. The smaller measures 1.5 x 0.2 cm. Submitted complete in C1.

D. Received in formalin labeled with the patient's name and "right pelvic node NFS" is an aggregate of yellow, fibrofatty tissue fragments measuring 3 x 3 cm. The fat is trimmed, and five probable lymph nodes are grossly identified. The largest measures 2 x 0.7 cm. The smallest measures 0.3 x 0.2 cm. Submitted complete in D1 and D2.

E. Received in formalin labeled with the patient's name and "bladder neck FS" is a gray-tan FS tissue fragment measuring 1.5 x 1 cm. Submitted complete in E1.

F. Received in formalin labeled with the patient's name and "prostate, vas & seminal vesicles NFS" is a radical prostatectomy specimen which includes a 50-gram prostate gland with attached seminal vesicles and vas deferens. The prostate gland measures 4.5 x 4 x 3 cm and has a shaggy capsule that is disrupted at the bladder resection margin and has been previously inked black on the left and blue on the right. The right seminal vesicle measures 1.5 x 1.5 cm, and the right vas deferens measures 1 x 0.5 cm. The left seminal vesicle measures 2.5 x 1 cm, and the left vas deferens measures 1 x 0.5 cm. Also, there is a portion of tissue between the bladder resection margin, which measures 1 x 1 x 1 cm. The inferior prostate is sectioned transversely, removed from the rest of the specimen, and sectioned from anterior to posterior parallel to the plane of the urethra. The remaining gland is serially sectioned transversely and shows a firm, focally nodular parenchyma. The seminal vesicles and vasa deferentia show no abnormalities. Representative sections submitted as follows: inferior prostate

Prepared for

on

[page 4 of 5]
to demonstrate apical margin submitted entirely anterior to posterior in F1-F6; bladder resection margin is shaved, serially sectioned, and submitted in F7-F8; complete section of the mid gland anterior F9-F10; posterior F11-F12; complete section of upper third of gland, anterior F13-F14; posterior F15-F16; posterior gland submitted in F17-F22; right seminal vesicle and vas deferens F23; left seminal vesicle and vas deferens F24; tissue from between the bladder resection margin submitted in F25.

Physicians

Procedure

A. AA ROUTINE H&E X1 BLOCK
H&E X1
B. AA ROUTINE H&E X1 BLOCK.1
H&E X1
B. AA ROUTINE H&E X1 BLOCK.2
H&E X1
B. AA ROUTINE H&E X1 BLOCK.3
H&E X1
B. AA ROUTINE H&E X1 BLOCK.4
H&E X1
B. AA ROUTINE H&E X1 BLOCK.5
H&E X1
C. AA ROUTINE H&E X1 BLOCK
H&E X1
D. AA ROUTINE H&E X1 BLOCK.1
H&E X1
D. AA ROUTINE H&E X1 BLOCK.2
H&E X1
E. AA ROUTINE H&E X1 BLOCK
H&E X1
F. AA ROUTINE H&E X1 BLOCK.1
H&E X1
F. AA ROUTINE H&E X1 BLOCK.2
H&E X1
F. AA ROUTINE H&E X1 BLOCK.3
H&E X1
F. AA ROUTINE H&E X1 BLOCK.4
H&E X1
F. AA ROUTINE H&E X1 BLOCK.5
H&E X1
F. AA ROUTINE H&E X1 BLOCK.6
H&E X1
F. AA ROUTINE H&E X1 BLOCK.7
H&E X1

Prepared for

[page 5 of 5]
F. AA ROUTINE H&E X1 BLOCK.8
H&E X1
F. AA ROUTINE H&E X1 BLOCK.9
H&E X1
F. AA ROUTINE H&E X1 BLOCK.10
H&E X1
F. AA ROUTINE H&E X1 BLOCK.11
H&E X1
F. AA ROUTINE H&E X1 BLOCK.12
H&E X1
F. AA ROUTINE H&E X1 BLOCK.13
H&E X1
F. AA ROUTINE H&E X1 BLOCK.14
H&E X1
F. AA ROUTINE H&E X1 BLOCK.15
H&E X1
F. AA ROUTINE H&E X1 BLOCK.16
H&E X1
F. AA ROUTINE H&E X1 BLOCK.17
H&E X1
F. AA ROUTINE H&E X1 BLOCK.18
H&E X1
F. AA ROUTINE H&E X1 BLOCK.19
H&E X1
F. AA ROUTINE H&E X1 BLOCK.20
H&E X1
F. AA ROUTINE H&E X1 BLOCK.21
H&E X1
F. AA ROUTINE H&E X1 BLOCK.22
H&E X1
F. AA ROUTINE H&E X1 BLOCK.23
H&E X1
F. AA ROUTINE H&E X1 BLOCK.24
H&E X1
F. AA ROUTINE H&E X1 BLOCK.25
H&E X1

Prepared for

Source: NCI Genomic Data Commons file d8498796-7294-483c-9720-7bf69801c578 (TCGA-J4-AATZ.369F71EC-186A-41DA-91F7-B0FD209BEC8F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).